Somatic mutation profile of tumor specimen TCGA-62-8395-01A (aliquot TCGA-62-8395-01A-11D-2323-08) from TCGA case TCGA-62-8395, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 80.2 years (29,311 days).
Specimen TCGA-62-8395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e5f3a9e2-129f-4907-9896-a06522bfa165.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-8395-10A (Blood Derived Normal), aliquot TCGA-62-8395-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edf20538-8946-4b5d-963a-c6e86b8ff11e

The open-access MAF lists 79 somatic variants for this specimen: 61 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Nonsense Mutation 6, Frame Shift Del 5, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3184_3187del p.Q1062Vfs*63 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs1114167551; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057519921, COSV67960034, COSV67960332, COSV67961305; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.2062A>T p.N688Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs1259726208, COSV100933172; called by muse, mutect2, varscan2
- ACOT7 | c.365C>T p.A122V (on ENST00000377855 / NM_181864.3; = p.A112V on NM_007274.4) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.59); catalogued as rs989978180, COSV64115612; called by muse, mutect2
- AKAP1 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100028138; called by muse, mutect2, varscan2
- AKAP1 | c.1115C>A p.A372E | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100028147; called by muse, mutect2, varscan2
- ANK1 | c.3864G>T p.L1288F | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV99226111; called by muse, mutect2, varscan2
- ANK1 | c.3820G>A p.E1274K | Missense Mutation (SNP) | VAF 198/733 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV99226113; called by muse, mutect2, varscan2
- ARSJ | c.298A>G p.T100A | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100192911; called by muse, mutect2, varscan2
- BABAM1 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs757371052, COSV63920514; called by muse, mutect2
- BRWD3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64746047; called by muse, mutect2
- CD300LF | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 15/251 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs1434035842, COSV100042834; called by muse, mutect2
- CFAP91 | c.1994C>A p.A665E | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99847315; called by muse, mutect2, varscan2
- CNTN6 | c.1816G>A p.V606M | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100611375; called by muse, mutect2, varscan2
- CNTNAP4 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100270033, COSV100271875; called by muse, mutect2
- COL13A1 | c.623G>C p.G208A (on ENST00000398978 / NM_001130103.2; = p.G170A on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100637627, COSV62569001; called by muse, mutect2
- DISP2 | c.2272del p.L758Cfs*39 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs1411673167; called by mutect2, pindel, varscan2
- DLGAP1 | c.1190C>G p.S397* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100232631; called by muse, mutect2, varscan2
- DOP1B | c.958T>G p.Y320D | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV101215649; called by muse, mutect2, varscan2
- EPB41L3 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100549783; called by muse, mutect2
- FRMD7 | c.1187C>G p.S396C | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100049153, COSV53745181; called by muse, mutect2, varscan2
- GCFC2 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.601); catalogued as COSV100319283, COSV100319637; called by muse, mutect2
- HAO1 | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101113262; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2276A>C p.Q759P | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV99523804; called by muse, mutect2, varscan2
- HSP90AB1 | c.137A>C p.N46T | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100807161; called by muse, mutect2
- IGHV3-11 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.091); catalogued as rs564357666; called by muse, mutect2, varscan2
- KCNK1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs1433149408, COSV64040123; called by muse, mutect2
- KIAA1614 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200280666; called by mutect2, varscan2
- KIF2A | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs1195921358, COSV101136576; called by muse, mutect2, varscan2
- KLHL15 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60139566; called by muse, mutect2, varscan2
- LARGE1 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.549); catalogued as rs777068842, COSV61668308; called by muse, mutect2, varscan2
- MAST2 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.241); catalogued as COSV100788520; called by muse, mutect2, varscan2
- MEF2C | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60929381; called by muse, mutect2
- MIER3 | c.1056C>G p.D352E (on ENST00000381199 / NM_001297599.2; = p.D351E on NM_152622.4) | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV101167653; called by muse, mutect2, varscan2
- MRRF | c.323A>G p.N108S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99938975; called by muse, mutect2, varscan2
- NCBP2 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as COSV100052140; called by muse, mutect2, varscan2
- OR10Z1 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV100779053; called by muse, mutect2, varscan2
- P2RY8 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV101184110; called by muse, mutect2
- PARD3 | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100632744; called by muse, mutect2, varscan2
- PHC2 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1364954396, COSV99931237; called by muse, mutect2, varscan2
- PKP4 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | catalogued as rs1260488077, COSV100733912; called by muse, mutect2, varscan2
- PPFIBP1 | c.1021G>C p.D341H (on ENST00000318304 / NM_177444.3; = p.D321H on NM_003622.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99945169; called by muse, mutect2
- RAP1GAP | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.747); catalogued as rs138045307; called by muse, mutect2, varscan2
- RGS14 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV101281717; called by muse, mutect2
- SAMD4B | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1568362940, COSV100080393, COSV100080507; called by muse, mutect2
- SLC9A7 | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100092471; called by muse, mutect2, varscan2
- SMC6 | c.2239G>C p.E747Q | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100705266; called by muse, mutect2
- SOHLH2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs201006259, COSV100499465; called by muse, mutect2, varscan2
- SORBS1 | c.333G>C p.E111D (on ENST00000361941 / NM_001034954.2; = p.E70D on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as rs773110235, COSV99528539; called by muse, mutect2, varscan2
- TBL1XR1 | c.1160T>C p.L387S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101467779; called by muse, mutect2, varscan2
- TET1 | c.2720A>G p.N907S | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as COSV101018587, COSV65384855; called by muse, mutect2, varscan2
- TUBB2B | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.305); catalogued as rs772860060, COSV52533325; called by muse, mutect2, varscan2
- TUBGCP5 | c.2333C>T p.S778F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs765163172; called by muse, mutect2
- TWNK | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99272853; called by muse, mutect2, varscan2
- USP28 | c.1424C>A p.S475* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV99135995; called by muse, mutect2, varscan2
- VIL1 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1277974771, COSV99945725; called by muse, mutect2, varscan2
- WAS | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.051); catalogued as CD951894, COSV100939516; called by muse, mutect2, varscan2
- DYNC1H1 | c.6132del p.D2045Tfs*4 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- FMNL2 | c.3173_3174del p.L1058Qfs*20 | Frame Shift Del (DEL) | VAF 38/245 reads (16%) | called by mutect2, pindel, varscan2
- STAG2 | c.513C>G p.F171L | Missense Mutation (SNP) | VAF 7/206 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- ZNF827 | c.703_706del p.M235Dfs*30 | Frame Shift Del (DEL) | VAF 18/79 reads (23%) | called by mutect2, pindel, varscan2
- ABCC3 | c.2277C>G p.V759= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99559485; called by muse, mutect2, varscan2
- ATP2B2 | c.2280G>A p.G760= (on ENST00000352432; = p.G726= on NM_001683.5) | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100660230; called by muse, mutect2, varscan2
- CCDC3 | c.765G>A p.P255= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs374950220; called by mutect2, varscan2
- CIAO3 | c.633C>T p.T211= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs747993603, COSV99285047; called by muse, mutect2, varscan2
- CTNNA1 | c.1020C>T p.V340= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV100243092; called by muse, mutect2, varscan2
- F8 | c.2470T>C p.L824= | Silent (SNP) | VAF 69/205 reads (34%) | catalogued as COSV100811687; called by muse, mutect2, varscan2
- IL12RB1 | c.93T>C p.F31= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1318111906, COSV100443131, COSV59099725; called by muse, mutect2
- LAMA3 | c.6291G>A p.A2097= (on ENST00000313654 / NM_198129.4; = p.A488= on NM_000227.6) | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs569425764, COSV52531966; called by muse, mutect2, varscan2
- PIEZO2 | c.7557C>T p.H2519= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as rs756393774, COSV99555266; called by muse, mutect2, varscan2
- RPA4 | c.456C>T p.N152= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100234075; called by muse, mutect2, varscan2
- SLAIN2 | c.1371A>T p.P457= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV99971759; called by muse, mutect2, varscan2
- SLC25A34 | c.852C>G p.L284= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV99606716; called by muse, mutect2
- SRBD1 | c.2124G>A p.V708= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as rs1416787199, COSV99765331; called by muse, mutect2, varscan2
- SYNPO2 | c.1089C>T p.S363= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as rs1294700671, COSV100205476; called by muse, mutect2, varscan2
- TLR9 | c.1035C>T p.Y345= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs374354848; called by muse, mutect2, varscan2
- WDR33 | c.2538G>A p.L846= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as COSV100460393; called by muse, mutect2
- KIR3DX1 | n.840C>A | RNA (SNP) | VAF 6/92 reads (7%) | catalogued as rs769232888, COSV99683506; called by muse, mutect2
- PCSK6 | c.1859-15764_1859-15735del | Intron (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel
